Gene-level copy-number profile of tumor specimen TCGA-NF-A4X2-01A from TCGA case TCGA-NF-A4X2, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage II; Age at diagnosis: 60.0 years (21,908 days).
Specimen TCGA-NF-A4X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.d5482714-ecfc-494f-8080-c141e993f770.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NF-A4X2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/755b4a72-7961-4240-8025-9507e7137834

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 173; copy number 1: 3,369; copy number 2: 25,409; copy number 3: 22,834; copy number 4: 6,306; copy number 5: 1,674; copy number 6: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NF-A4X2-01A-11D-A28Q-01): tumor purity 0.81, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 173 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,488,963–48,578,088, 5 genes (within-gene range 0–2): RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462.
- chr17:19,189,665–22,706,703, 168 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,720 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,992,685–154,155,116, 1 gene, copy number 5 (within-gene range 3–5): NUP210L.
- chr1:154,078,866–189,993,097, 893 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–31,530,232, 826 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,369. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
